Somatic mutation profile of tumor specimen TCGA-44-2657-01A (aliquot TCGA-44-2657-01A-01D-1105-08) from TCGA case TCGA-44-2657, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 74.7 years (27,298 days).
Specimen TCGA-44-2657-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b91dfde6-87fb-4a9f-8aac-07e02098d860.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-44-2657-10A (Blood Derived Normal), aliquot TCGA-44-2657-10A-01D-1105-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/db8e00e7-5ad7-4fb7-81e7-beabe6700c5f

The open-access MAF lists 425 somatic variants for this specimen: 328 protein-altering or splice-affecting, 91 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 294, Silent 91, Nonsense Mutation 16, Splice Site 11, Frame Shift Del 6, Intron 2, Translation Start Site 1, 5'Flank 1, 3'UTR 1, RNA 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- A4GNT | c.600C>A p.H200Q | Missense Mutation (SNP) | VAF 20/212 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as COSV99367727; called by muse, mutect2
- ABCB1 | c.3231C>A p.S1077R | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55948456; called by muse, mutect2
- ABCB7 | c.2115G>C p.W705C (on ENST00000373394 / NM_001271696.3; = p.W706C on NM_004299.6) | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53719022; called by muse, varscan2
- ABCB9 | c.418G>A p.V140M | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.773); catalogued as rs370168137; called by muse, mutect2, varscan2
- ABLIM1 | c.2143A>T p.I715L | Missense Mutation (SNP) | VAF 31/176 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.078); catalogued as COSV53303368, COSV53305343; called by muse, mutect2, varscan2
- ADAMTS16 | c.295C>A p.L99I | Missense Mutation (SNP) | VAF 52/164 reads (32%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.626); catalogued as COSV56984187; called by muse, mutect2, varscan2
- ADAMTS4 | c.2200G>T p.G734C | Missense Mutation (SNP) | VAF 16/139 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV63489667; called by muse, mutect2
- ADCY1 | c.2760G>T p.K920N | Missense Mutation (SNP) | VAF 34/244 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52032629; called by muse, mutect2, varscan2
- ADGRB3 | c.2846A>T p.H949L | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53240087, COSV53251304; called by muse, mutect2, varscan2
- ADGRF5 | c.3296G>T p.S1099I | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.959); catalogued as COSV51932141, COSV51939043; called by muse, mutect2, varscan2
- ADGRG2 | c.412C>A p.Q138K (on ENST00000379869 / NM_001079858.3; = p.Q135K on NM_005756.4) | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.044); catalogued as COSV61338403; called by muse, mutect2, varscan2
- ADGRG4 | c.6206C>A p.T2069N | Missense Mutation (SNP) | VAF 20/244 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.048); catalogued as COSV54953090; called by muse, mutect2
- ADGRL3 | c.1579G>T p.V527L (on ENST00000506720 / NM_001322402.2; = p.V459L on NM_015236.6) | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV72230133; called by muse, mutect2, varscan2
- ADH1B | c.75G>T p.E25D | Missense Mutation (SNP) | VAF 22/148 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59295832; called by muse, mutect2, varscan2
- AKNAD1 | c.118G>T p.G40C | Missense Mutation (SNP) | VAF 29/188 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.054); catalogued as COSV62197051, COSV62200115; called by muse, mutect2, varscan2
- ALPK3 | c.1895G>T p.R632M | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.533); catalogued as COSV99360366; called by muse, mutect2, varscan2
- APOB | c.1160A>C p.Q387P | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.815); catalogued as COSV99264141; called by muse, mutect2, varscan2
- APOB | c.1159C>A p.Q387K | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.155); catalogued as COSV99264145; called by muse, mutect2, varscan2
- ARHGAP33 | c.667G>C p.D223H | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.719); catalogued as COSV50121132; called by muse, mutect2
- ARHGAP36 | c.1328C>T p.S443F | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.191); catalogued as COSV52265474; called by muse, mutect2
- ARID2 | c.3457G>T p.G1153C | Missense Mutation (SNP) | VAF 26/171 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV57600731; called by muse, mutect2, varscan2
- ARID5A | c.1409A>T p.D470V | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.368); catalogued as COSV62590913; called by muse, mutect2, varscan2
- ASB15 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 44/267 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV51924961; called by muse, mutect2, varscan2
- ASMT | c.755G>T p.R252M (on ENST00000381229; = p.R280M on NM_004043.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 74/353 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67109719, COSV67109739; called by muse, mutect2, varscan2
- AVPR1A | c.32C>A p.P11H | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.166); catalogued as COSV54546106; called by muse, mutect2, varscan2
- B4GALT6 | c.971A>T p.H324L | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV52703091; called by muse, mutect2, varscan2
- BMP5 | c.884A>G p.Q295R | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.261); catalogued as COSV63702264; called by muse, mutect2, varscan2
- BRPF3 | c.3438G>T p.Q1146H | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60206767; called by muse, mutect2, varscan2
- BTBD3 | c.724C>T p.Q242* | Nonsense Mutation (SNP) | VAF 24/133 reads (18%) | catalogued as COSV54778642; called by muse, mutect2, varscan2
- C1QB | c.80T>G p.L27R | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV59245189; called by muse, mutect2, varscan2
- C2CD5 | c.800+2T>G p.X267_splice | Splice Site (SNP) | VAF 9/89 reads (10%) | catalogued as COSV61723900; called by muse, mutect2
- C4orf51 | c.80G>C p.R27T | Missense Mutation (SNP) | VAF 29/184 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs545069205, COSV71264022; called by muse, mutect2, varscan2
- CARD14 | c.1157G>T p.R386L | Missense Mutation (SNP) | VAF 24/160 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs535721220, COSV60122714, COSV60123722; called by muse, mutect2, varscan2
- CAT | c.1027A>G p.I343V | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.018); catalogued as COSV53810852; called by muse, mutect2, varscan2
- CBLN2 | c.374G>T p.G125V | Missense Mutation (SNP) | VAF 13/123 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54050503, COSV99504185; called by muse, mutect2, varscan2
- CBLN2 | c.373G>T p.G125C | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99504188; called by muse, mutect2, varscan2
- CCDC146 | c.1126G>A p.D376N | Missense Mutation (SNP) | VAF 29/186 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.818); catalogued as COSV53546361, COSV53546465; called by muse, mutect2, varscan2
- CCDC47 | c.292G>A p.D98N | Missense Mutation (SNP) | VAF 21/175 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as COSV56722610; called by muse, mutect2, varscan2
- CCDC54 | c.80C>A p.S27Y | Missense Mutation (SNP) | VAF 49/217 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.046); catalogued as COSV53758354; called by muse, mutect2, varscan2
- CD1E | c.521G>T p.R174L | Missense Mutation (SNP) | VAF 17/157 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV63770616, COSV63772837; called by muse, mutect2, varscan2
- CD96 | c.1325G>T p.G442V (on ENST00000283285 / NM_198196.3; = p.G426V on NM_005816.5) | Missense Mutation (SNP) | VAF 47/225 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.403); catalogued as rs1056687298, COSV51914715; called by muse, mutect2, varscan2
- CDH10 | c.1730G>A p.S577N | Missense Mutation (SNP) | VAF 8/101 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52576472; called by muse, mutect2
- CDH8 | c.1262C>T p.T421I | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as rs1309600748, COSV54858945; called by mutect2, varscan2
- CDH9 | c.2350G>T p.D784Y | Missense Mutation (SNP) | VAF 44/273 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.516); catalogued as COSV50265112; called by muse, mutect2, varscan2
- CHL1 | c.3156G>T p.W1052C (on ENST00000397491 / NM_001253387.1; = p.W1068C on NM_006614.4) | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.719); catalogued as COSV56590287, COSV99852269; called by muse, mutect2, varscan2
- CILP2 | c.2520C>A p.D840E | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV52273846; called by muse, mutect2, varscan2
- CLEC12B | c.650G>T p.W217L | Missense Mutation (SNP) | VAF 32/149 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58863099; called by muse, mutect2, varscan2
- CNTN5 | c.1147C>A p.Q383K | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.412); catalogued as rs200696545; called by muse, mutect2, varscan2
- CNTNAP2 | c.899G>T p.R300L | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.888); catalogued as COSV62163736, COSV62175685; called by muse, mutect2, varscan2
- COL4A2 | c.2711C>A p.P904H | Missense Mutation (SNP) | VAF 16/157 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64626925; called by muse, mutect2
- COL4A5 | c.1880C>T p.P627L | Missense Mutation (SNP) | VAF 15/147 reads (10%) | SIFT tolerated (0.89); PolyPhen benign (0.015); catalogued as COSV60359198; called by muse, mutect2
- COL4A6 | c.2254G>T p.D752Y | Missense Mutation (SNP) | VAF 14/172 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57862979; called by muse, mutect2
- CPA3 | c.212G>A p.S71N | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated (0.48); PolyPhen benign (0.011); catalogued as COSV56044568; called by muse, mutect2
- CPS1 | c.3928G>T p.A1310S | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.46); catalogued as rs754166196, COSV51806494; called by muse, mutect2, varscan2
- CSMD1 | c.8317G>A p.G2773S (on ENST00000520002; = p.G2772S on NM_033225.6) | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201814026; called by muse, mutect2, varscan2
- CSN2 | c.247C>A p.P83T | Missense Mutation (SNP) | VAF 14/138 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.268); catalogued as COSV100778746; called by muse, mutect2
- CT45A10 | c.397G>T p.E133* | Nonsense Mutation (SNP) | VAF 24/208 reads (12%) | catalogued as COSV65921097, COSV65921147, COSV65921162; called by muse, mutect2, varscan2
- CUL7 | c.409C>G p.L137V | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT tolerated (0.6); PolyPhen benign (0.076); catalogued as COSV54814962; called by muse, mutect2, varscan2
- CXorf56 | c.597G>T p.K199N (on ENST00000536133 / NM_001170570.2; = p.K213N on NM_022101.4) | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.265); catalogued as COSV57437984; called by muse, mutect2, varscan2
- CXorf66 | c.842C>A p.P281H | Missense Mutation (SNP) | VAF 18/244 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.215); catalogued as COSV65169070; called by muse, mutect2
- CYP27A1 | c.1283A>T p.H428L | Missense Mutation (SNP) | VAF 29/191 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV51467660; called by muse, mutect2, varscan2
- CYYR1 | c.20C>A p.P7H | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.814); catalogued as COSV54830113; called by muse, mutect2, varscan2
- DACT1 | c.1062G>T p.R354S | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100241701, COSV60020208; called by muse, mutect2, varscan2
- DCLK3 | c.310C>A p.P104T | Missense Mutation (SNP) | VAF 22/290 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV69362871; called by muse, mutect2
- DDX60 | c.1940G>T p.C647F | Missense Mutation (SNP) | VAF 20/218 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.118); catalogued as rs137933604, COSV67095932; called by muse, mutect2
- DHRS7C | c.915G>T p.K305N (on ENST00000330255 / NM_001220493.2; = p.K304N on NM_001105571.3) | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.024); catalogued as COSV57650336; called by muse, mutect2
- DIP2A | c.3540G>C p.K1180N | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.551); catalogued as COSV59475327; called by muse, mutect2, varscan2
- DLGAP3 | c.916G>T p.G306C | Missense Mutation (SNP) | VAF 63/146 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV52392917; called by muse, mutect2, varscan2
- DNAH9 | c.2131G>T p.E711* | Nonsense Mutation (SNP) | VAF 53/237 reads (22%) | catalogued as COSV52343867; called by muse, mutect2, varscan2
- DRD2 | c.740C>A p.P247H | Missense Mutation (SNP) | VAF 39/273 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as COSV100669363; called by muse, mutect2, varscan2
- DRD2 | c.739C>A p.P247T | Missense Mutation (SNP) | VAF 41/271 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.071); catalogued as COSV60758424; called by muse, mutect2, varscan2
- DRD3 | c.700G>T p.V234F | Missense Mutation (SNP) | VAF 60/301 reads (20%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.462); catalogued as COSV55679590; called by muse, mutect2, varscan2
- DUSP22 | c.389G>A p.G130D | Missense Mutation (SNP) | VAF 14/278 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1157857137, COSV60525524; called by muse, mutect2
- EHBP1L1 | c.2324G>T p.G775V | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.462); catalogued as COSV100499721; called by muse, mutect2
- EPHA3 | c.1365G>C p.L455F | Missense Mutation (SNP) | VAF 51/301 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60700466, COSV60722652; called by muse, mutect2, varscan2
- ERMN | c.241+1G>T p.X81_splice | Splice Site (SNP) | VAF 14/118 reads (12%) | catalogued as COSV101263023; called by muse, mutect2, varscan2
- ESPNL | c.623C>G p.A208G | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.096); catalogued as COSV58033675; called by muse, mutect2
- FAM135B | c.368+1G>T p.X123_splice | Splice Site (SNP) | VAF 11/76 reads (14%) | catalogued as COSV50524388, COSV50542161; called by muse, mutect2, varscan2
- FAM32A | c.332C>T p.T111M | Missense Mutation (SNP) | VAF 8/91 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.09); catalogued as COSV99655300; called by muse, mutect2, varscan2
- FAT1 | c.8911A>G p.T2971A | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV71673267; called by muse, mutect2, varscan2
- FAT3 | c.7705A>T p.S2569C | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.694); catalogued as COSV53094910; called by muse, mutect2, varscan2
- FCRL2 | c.589G>T p.V197L | Missense Mutation (SNP) | VAF 16/190 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV100829835, COSV63833207; called by muse, mutect2
- FCRL3 | c.1891G>C p.D631H | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.052); catalogued as COSV63840600; called by muse, mutect2
- FER1L6 | c.1231C>A p.Q411K | Missense Mutation (SNP) | VAF 46/195 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.036); catalogued as COSV67549181; called by muse, mutect2, varscan2
- FKBP6 | c.894-1G>C p.X298_splice | Splice Site (SNP) | VAF 18/371 reads (5%) | catalogued as COSV52719641; called by muse, mutect2
- FLG | c.10334G>A p.R3445K | Missense Mutation (SNP) | VAF 47/818 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.54); catalogued as rs1313286200, COSV64239749; called by muse, mutect2
- FLG | c.6200C>A p.P2067H | Missense Mutation (SNP) | VAF 105/643 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs1313871676, COSV64239753; called by muse, mutect2, varscan2
- FLG2 | c.45C>G p.F15L | Missense Mutation (SNP) | VAF 21/174 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV66167667; called by muse, mutect2, varscan2
- FLII | c.2677G>C p.A893P | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV57497335; called by muse, mutect2
- FLT4 | c.2117C>A p.A706E | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs747033940, COSV56103678; called by muse, mutect2, varscan2
- FOXI1 | c.648G>C p.R216S | Missense Mutation (SNP) | VAF 18/156 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as COSV60388146, COSV60388405; called by muse, mutect2
- FRAS1 | c.1420A>T p.T474S | Missense Mutation (SNP) | VAF 28/203 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.025); catalogued as COSV53601611; called by muse, mutect2, varscan2
- FRMPD3 | c.25G>T p.V9F | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated, low confidence (0.1); catalogued as COSV99345797; called by muse, mutect2, varscan2
- FSTL1 | c.678C>A p.F226L | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.578); catalogued as COSV55232876; called by muse, mutect2
- FUT9 | c.32C>A p.P11Q | Missense Mutation (SNP) | VAF 9/175 reads (5%) | SIFT tolerated (0.39); PolyPhen benign (0.183); catalogued as COSV100133212; called by muse, mutect2
- FXR1 | c.1349C>T p.S450L | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.187); catalogued as COSV59762152; called by muse, mutect2, varscan2
- FYCO1 | c.3080G>T p.S1027I | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as COSV56115076; called by muse, mutect2
- FYCO1 | c.97G>T p.E33* | Nonsense Mutation (SNP) | VAF 21/197 reads (11%) | catalogued as COSV56113118, COSV56115086; called by muse, mutect2
- GATAD2A | c.55C>G p.P19A | Missense Mutation (SNP) | VAF 29/175 reads (17%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV53068356; called by muse, mutect2, varscan2
- GBP5 | c.1066A>G p.R356G | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.664); catalogued as COSV58592183; called by muse, mutect2, varscan2
- GCH1 | c.691T>A p.L231M | Missense Mutation (SNP) | VAF 18/202 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.741); catalogued as COSV54301558; called by muse, mutect2
- GIPC3 | c.688G>T p.A230S | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.762); catalogued as COSV59258720; called by muse, mutect2, varscan2
- GLI3 | c.481G>T p.A161S | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.036); catalogued as COSV67887104; called by muse, mutect2
- GLRA3 | c.540G>T p.M180I | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV56859764; called by muse, mutect2
- GPRASP1 | c.1319G>T p.W440L | Missense Mutation (SNP) | VAF 20/259 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV64356456; called by muse, mutect2
- GPRASP1 | c.1320G>T p.W440C | Missense Mutation (SNP) | VAF 20/258 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100850928; called by muse, mutect2
- GRM4 | c.2660C>A p.S887Y | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.202); catalogued as COSV65212120; called by muse, mutect2, varscan2
- GULP1 | c.389G>T p.S130I | Missense Mutation (SNP) | VAF 18/167 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV63066505; called by muse, mutect2, varscan2
- H1-5 | c.86C>G p.A29G | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV58899637; called by muse, mutect2
- H2BW1 | c.92G>C p.G31A | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.107); catalogued as COSV54219797, COSV54219962; called by muse, mutect2
- HAS1 | c.649G>T p.E217* | Nonsense Mutation (SNP) | VAF 6/54 reads (11%) | catalogued as COSV55786943, COSV55788524; called by muse, mutect2, varscan2
- HERC2 | c.11227C>T p.L3743F | Missense Mutation (SNP) | VAF 14/210 reads (7%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs769879755, COSV55316751; called by muse, mutect2
- HHIPL2 | c.853C>A p.H285N | Missense Mutation (SNP) | VAF 50/432 reads (12%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as COSV58564294; called by muse, varscan2
- HIRA | c.1457G>T p.G486V | Missense Mutation (SNP) | VAF 22/302 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.383); catalogued as rs1317566167, COSV99600010; called by muse, mutect2
- HIRA | c.1456G>T p.G486C | Missense Mutation (SNP) | VAF 22/300 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as COSV99600015; called by muse, mutect2
- HSP90AA1 | c.1734A>G p.I578M | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.843); catalogued as rs756187710, COSV53488068; called by muse, mutect2, varscan2
- HSP90AA1 | c.632C>T p.S211F | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776320264, COSV53488088; called by muse, mutect2, varscan2
- HTR3C | c.292C>A p.P98T | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as COSV59174792; called by muse, mutect2
- IFIH1 | c.2057T>C p.M686T | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as COSV55125695; called by muse, mutect2, varscan2
- IFT22 | c.443C>G p.S148* | Nonsense Mutation (SNP) | VAF 12/151 reads (8%) | catalogued as rs1177778210, COSV59527026; called by muse, mutect2
- IGFN1 | c.3320G>T p.G1107V (on ENST00000295591 / NM_001367841.1; = p.G3564V on NM_001164586.2) | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55165252, COSV55170034; called by muse, mutect2, varscan2
- IGSF1 | c.3881C>A p.S1294* | Nonsense Mutation (SNP) | VAF 44/470 reads (9%) | catalogued as COSV63836858; called by muse, mutect2, varscan2
- IGSF22 | c.697-1G>T p.X233_splice | Splice Site (SNP) | VAF 26/272 reads (10%) | catalogued as COSV60032622; called by muse, mutect2
- IGSF5 | c.1112G>A p.C371Y | Missense Mutation (SNP) | VAF 24/190 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV66029773; called by muse, mutect2, varscan2
- IL21R | c.104G>T p.C35F | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100559886; called by muse, mutect2, varscan2
- IL31RA | c.1826T>A p.L609Q | Missense Mutation (SNP) | VAF 30/184 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.075); catalogued as COSV61693642; called by muse, mutect2, varscan2
- ILDR2 | c.1039A>T p.S347C | Missense Mutation (SNP) | VAF 30/297 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.628); catalogued as COSV99613374; called by muse, mutect2, varscan2
- INSYN2A | c.1004C>G p.P335R | Missense Mutation (SNP) | VAF 55/314 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.748); catalogued as COSV54735355; called by muse, mutect2, varscan2
- INTS13 | c.2086G>C p.E696Q | Missense Mutation (SNP) | VAF 20/155 reads (13%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.107); catalogued as COSV53901976; called by muse, mutect2, varscan2
- JAKMIP2 | c.251A>G p.E84G | Missense Mutation (SNP) | VAF 74/456 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV54601353; called by muse, mutect2, varscan2
- JPH2 | c.49G>T p.G17C | Missense Mutation (SNP) | VAF 28/135 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60696719; called by muse, mutect2, varscan2
- KCNA7 | c.892C>A p.L298M | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); catalogued as COSV55503823, COSV99671846; called by muse, mutect2, varscan2
- KCNE5 | c.292T>A p.C98S | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV100927698; called by muse, mutect2
- KCNH7 | c.3132G>T p.R1044S | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV59792594; called by muse, mutect2, varscan2
- KCNMA1 | c.2835G>T p.L945F (on ENST00000286628 / NM_001161352.2; = p.L887F on NM_002247.4) | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54239664; called by muse, mutect2, varscan2
- KCTD8 | c.1219C>T p.R407C | Missense Mutation (SNP) | VAF 52/380 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as rs143160739, COSV100759683, COSV63585505, COSV63589266; called by muse, mutect2, varscan2
- KIAA1755 | c.904T>G p.S302A | Missense Mutation (SNP) | VAF 23/423 reads (5%) | SIFT tolerated (0.51); PolyPhen benign (0.006); catalogued as COSV54075262; called by muse, mutect2
- KLHL2 | c.1040-1G>T p.X347_splice | Splice Site (SNP) | VAF 73/449 reads (16%) | catalogued as COSV56975752; called by muse, mutect2, varscan2
- KLHL5 | c.2153G>T p.G718V | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54673158; called by muse, mutect2
- KLK15 | c.367C>A p.R123S | Missense Mutation (SNP) | VAF 36/139 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.73); catalogued as COSV56825833, COSV56826507; called by muse, mutect2, varscan2
- KMT2C | c.8041C>G p.P2681A | Missense Mutation (SNP) | VAF 15/140 reads (11%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV51425823; called by muse, mutect2
- KMT2C | c.1223C>T p.T408M | Missense Mutation (SNP) | VAF 26/159 reads (16%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.572); catalogued as rs773970643, COSV51425836; called by muse, mutect2, varscan2
- LCOR | c.1522G>C p.G508R | Missense Mutation (SNP) | VAF 25/143 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53715183; called by muse, mutect2, varscan2
- LIG1 | c.1732G>A p.A578T | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.124); catalogued as rs375683198; called by muse, mutect2, varscan2
- LRBA | c.2305G>T p.A769S | Missense Mutation (SNP) | VAF 36/243 reads (15%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.772); catalogued as COSV63952563; called by muse, mutect2, varscan2
- LRFN5 | c.1048A>T p.K350* | Nonsense Mutation (SNP) | VAF 37/195 reads (19%) | catalogued as COSV53250678; called by muse, mutect2, varscan2
- LRRC75A | c.560C>T p.S187F (on ENST00000470794 / NM_001113567.3; = p.L148= on NM_207387.4) | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.71); PolyPhen benign (0.229); catalogued as COSV100798502; called by mutect2, varscan2
- LRRK2 | c.3347+1G>T p.X1116_splice | Splice Site (SNP) | VAF 22/140 reads (16%) | catalogued as COSV54149114; called by muse, mutect2, varscan2
- LSP1 | c.985G>T p.E329* | Nonsense Mutation (SNP) | VAF 17/116 reads (15%) | catalogued as COSV61133517, COSV61133842; called by muse, mutect2, varscan2
- LTF | c.1549G>T p.D517Y | Missense Mutation (SNP) | VAF 20/210 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.705); catalogued as COSV51607030; called by muse, mutect2
- MACF1 | c.21646G>T p.G7216C (on ENST00000372915; = p.G5261C on NM_012090.5) | Missense Mutation (SNP) | VAF 47/120 reads (39%) | catalogued as COSV57115113; called by muse, mutect2, varscan2
- MAGEB18 | c.797G>C p.R266P | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.933); catalogued as COSV57463648; called by muse, mutect2, varscan2
- MAP3K15 | c.2505G>T p.W835C | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58827894; called by muse, mutect2, varscan2
- MET | c.944A>G p.N315S | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59259468; called by muse, mutect2, varscan2
- METTL17 | c.40T>C p.W14R | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.156); catalogued as COSV59555700; called by muse, mutect2, varscan2
- MICAL3 | c.3841C>T p.R1281C | Missense Mutation (SNP) | VAF 18/142 reads (13%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.003); catalogued as rs747674587, COSV71588224, COSV71588421; called by muse, mutect2, varscan2
- MIOS | c.1126G>C p.E376Q | Missense Mutation (SNP) | VAF 24/164 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.006); catalogued as COSV60767887; called by muse, mutect2, varscan2
- MS4A1 | c.32C>A p.T11N | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as COSV61941943; called by muse, mutect2
- MS4A5 | c.12C>A p.S4R | Missense Mutation (SNP) | VAF 33/237 reads (14%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV55740388; called by muse, mutect2, varscan2
- MTERF3 | c.950C>A p.T317N | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.365); catalogued as COSV54632338; called by muse, mutect2, varscan2
- MUC17 | c.5698A>C p.T1900P | Missense Mutation (SNP) | VAF 64/544 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); catalogued as COSV100072052; called by muse, varscan2
- MUC17 | c.9223A>T p.S3075C | Missense Mutation (SNP) | VAF 94/321 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as rs765294120, COSV60284832; called by muse, mutect2, varscan2
- MUC17 | c.10826C>A p.T3609N | Missense Mutation (SNP) | VAF 29/249 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV60284842; called by muse, mutect2, varscan2
- MUSK | c.887A>T p.K296M | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV51882726; called by muse, varscan2
- MYBL2 | c.1693C>T p.P565S | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.898); catalogued as COSV53828952; called by muse, mutect2, varscan2
- MYLK | c.2612G>T p.G871V | Missense Mutation (SNP) | VAF 35/188 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV60608016; called by muse, mutect2, varscan2
- MYO18B | c.455A>T p.D152V | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs764715379, COSV59130427; called by muse, mutect2, varscan2
- MYOCD | c.2734C>A p.P912T | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV58501121; called by muse, mutect2, varscan2
- MYPN | c.722C>A p.A241D | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.05); catalogued as COSV62732708; called by muse, mutect2, varscan2
- NAT10 | c.2266G>T p.D756Y | Missense Mutation (SNP) | VAF 26/178 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as COSV57663071; called by muse, mutect2, varscan2
- NEB | c.16493T>A p.L5498Q | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); catalogued as COSV51053405; called by muse, mutect2, varscan2
- NEK5 | c.1211C>A p.P404H | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.819); catalogued as COSV62879460; called by mutect2, varscan2
- NETO2 | c.301C>T p.R101W | Missense Mutation (SNP) | VAF 19/265 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752836648, COSV57452136; called by muse, mutect2
- NF1 | c.5003G>T p.G1668V (on ENST00000358273 / NM_001042492.3; = p.G1647V on NM_000267.3) | Missense Mutation (SNP) | VAF 52/212 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.16); catalogued as rs1555533332, COSV55985792; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NID1 | c.2075A>T p.Q692L | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV51618090; called by muse, mutect2, varscan2
- NOTCH1 | c.766G>C p.E256Q | Missense Mutation (SNP) | VAF 47/301 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0.011); catalogued as COSV53041305; called by muse, mutect2, varscan2
- NOVA1 | c.739A>T p.S247C | Missense Mutation (SNP) | VAF 40/215 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1030035421, COSV57474619; called by muse, mutect2, varscan2
- NPAP1 | c.182C>A p.A61E | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV61505804; called by muse, mutect2, varscan2
- NPM1 | c.440G>A p.G147D | Missense Mutation (SNP) | VAF 26/332 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.072); catalogued as COSV51553226; called by muse, mutect2
- NPR3 | c.259G>T p.G87W | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.836); catalogued as COSV54086238; called by muse, mutect2
- NRK | c.982A>G p.R328G | Missense Mutation (SNP) | VAF 2/10 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV54593006; called by muse, mutect2
- NRROS | c.1617G>T p.R539S | Missense Mutation (SNP) | VAF 27/266 reads (10%) | SIFT tolerated (0.57); PolyPhen benign (0.138); catalogued as COSV60745359; called by muse, mutect2, varscan2
- OBSCN | c.6944G>T p.R2315L | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.491); catalogued as COSV52759375; called by muse, mutect2, varscan2
- ODF1 | c.749T>C p.L250S | Missense Mutation (SNP) | VAF 18/290 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV53432157; called by muse, mutect2
- OOSP2 | c.31G>C p.V11L | Missense Mutation (SNP) | VAF 21/177 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV53928509; called by muse, mutect2, varscan2
- OR10W1 | c.861G>T p.E287D | Missense Mutation (SNP) | VAF 25/241 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.062); catalogued as COSV67720342; called by muse, mutect2, varscan2
- OR2G2 | c.266G>T p.W89L | Missense Mutation (SNP) | VAF 22/234 reads (9%) | SIFT tolerated (0.65); PolyPhen benign (0.09); catalogued as COSV60740004; called by muse, mutect2
- OR2T11 | c.275T>G p.V92G | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.206); catalogued as COSV58185333; called by muse, mutect2, varscan2
- OR2T34 | c.695G>T p.R232M | Missense Mutation (SNP) | VAF 31/207 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV60899992, COSV60900064; called by muse, mutect2, varscan2
- OR4D11 | c.719G>T p.C240F | Missense Mutation (SNP) | VAF 39/393 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57585301; called by muse, mutect2, varscan2
- OR56A3 | c.569G>T p.R190I | Missense Mutation (SNP) | VAF 18/158 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.03); catalogued as COSV61568800; called by muse, mutect2, varscan2
- OR5B3 | c.310G>T p.A104S | Missense Mutation (SNP) | VAF 25/142 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.015); catalogued as COSV58676800; called by muse, mutect2, varscan2
- OR6K6 | c.634G>T p.V212L (on ENST00000368144; = p.V188L on NM_001005184.1) | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT tolerated (0.62); PolyPhen benign (0.123); catalogued as COSV63743873; called by muse, mutect2, varscan2
- OR8I2 | c.463A>G p.S155G | Missense Mutation (SNP) | VAF 13/150 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV100135900; called by muse, mutect2, varscan2
- OR9Q2 | c.467C>A p.A156D | Missense Mutation (SNP) | VAF 20/135 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV61111696, COSV61112180; called by muse, mutect2, varscan2
- PABPC5 | c.263C>T p.P88L | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); catalogued as COSV57040025; called by muse, mutect2, varscan2
- PABPC5 | c.372C>A p.Y124* | Nonsense Mutation (SNP) | VAF 46/277 reads (17%) | catalogued as COSV57040040; called by muse, mutect2, varscan2
- PAK5 | c.1956G>T p.M652I | Missense Mutation (SNP) | VAF 24/177 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV62024741; called by muse, mutect2, varscan2
- PARP4 | c.2758+1G>T p.X920_splice | Splice Site (SNP) | VAF 31/259 reads (12%) | catalogued as COSV67961256; called by muse, mutect2, varscan2
- PCDH10 | c.484A>T p.T162S | Missense Mutation (SNP) | VAF 21/165 reads (13%) | SIFT tolerated (1); PolyPhen probably damaging (0.978); catalogued as COSV52091077; called by muse, mutect2, varscan2
- PCDH11X | c.855C>A p.H285Q | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.034); catalogued as COSV100009205; called by muse, mutect2, varscan2
- PCDH11X | c.3250G>T p.G1084C | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.503); catalogued as COSV53455360; called by muse, mutect2, varscan2
- PCDH8 | c.31T>A p.C11S | Missense Mutation (SNP) | VAF 13/128 reads (10%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.007); catalogued as COSV58811688; called by muse, varscan2
- PCDHA6 | c.2272G>T p.V758L | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.007); catalogued as COSV65343295; called by muse, mutect2, varscan2
- PCDHB12 | c.508T>C p.Y170H | Missense Mutation (SNP) | VAF 21/147 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1554286655, COSV53394950; called by muse, mutect2, varscan2
- PCDHB13 | c.643G>T p.A215S | Missense Mutation (SNP) | VAF 31/183 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53394957; called by muse, mutect2, varscan2
- PCDHB4 | c.1871G>T p.R624L | Missense Mutation (SNP) | VAF 24/157 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as COSV52021296; called by muse, mutect2, varscan2
- PCDHB8 | c.299C>T p.T100I | Missense Mutation (SNP) | VAF 12/161 reads (7%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.007); catalogued as COSV99176185; called by muse, mutect2, varscan2
- PCDHGC5 | c.1071C>A p.N357K | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.068); catalogued as COSV52748168, COSV52758583; called by muse, mutect2, varscan2
- PDCD2 | c.848G>C p.C283S | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99388393; called by muse, mutect2
- PDE1A | c.1175G>T p.G392V | Missense Mutation (SNP) | VAF 35/237 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59513435, COSV59519607; called by muse, mutect2, varscan2
- PDE1B | c.11C>A p.S4Y | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.825); catalogued as COSV54491410, COSV54495541; called by muse, mutect2, varscan2
- PDZD4 | c.2157C>A p.N719K | Missense Mutation (SNP) | VAF 9/140 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as COSV51246066; called by muse, mutect2
- PEAR1 | c.1907C>A p.T636N | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.338); catalogued as COSV52772249; called by muse, mutect2, varscan2
- PFKFB3 | c.1391C>T p.P464L | Missense Mutation (SNP) | VAF 18/134 reads (13%) | PolyPhen benign (0.014); catalogued as COSV57988012; called by muse, mutect2, varscan2
- PIK3R4 | c.572G>T p.R191L | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV63240095, COSV63243797; called by muse, mutect2, varscan2
- PIWIL3 | c.2074G>C p.E692Q | Missense Mutation (SNP) | VAF 18/160 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs753768633, COSV59994562; called by muse, mutect2, varscan2
- PKD1L1 | c.4387A>T p.S1463C | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV56961911; called by muse, mutect2, varscan2
- PKP2 | c.255G>T p.E85D | Missense Mutation (SNP) | VAF 20/167 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1366955346, COSV50728265; called by muse, mutect2, varscan2
- PLAC1 | c.193C>A p.H65N | Missense Mutation (SNP) | VAF 31/272 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.845); catalogued as rs1450099672, COSV100821487; called by muse, mutect2, varscan2
- PLCB4 | c.2489-1G>T p.X830_splice | Splice Site (SNP) | VAF 10/87 reads (11%) | catalogued as COSV53797963; called by muse, mutect2, varscan2
- PLCD3 | c.1116G>T p.R372S | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs376005032, COSV100504129; called by muse, mutect2, varscan2
- PMFBP1 | c.315G>T p.Q105H | Missense Mutation (SNP) | VAF 44/249 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52819977, COSV52822574; called by muse, mutect2, varscan2
- POLR3A | c.979G>T p.G327C | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV64930731; called by muse, mutect2, varscan2
- PON3 | c.215C>T p.P72L | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV55698791; called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.577G>T p.D193Y | Missense Mutation (SNP) | VAF 125/379 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV53451982; called by muse, mutect2, varscan2
- PRPF6 | c.38C>T p.A13V | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV53868476; called by muse, mutect2, varscan2
- PRPS1 | c.244G>A p.A82T | Missense Mutation (SNP) | VAF 45/381 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV65054249; called by muse, mutect2, varscan2
- PRRC2A | c.2209G>T p.G737C | Missense Mutation (SNP) | VAF 18/129 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65685973; called by muse, mutect2, varscan2
- PSMC6 | c.524G>T p.R175L (on ENST00000612399; = p.R161L on NM_002806.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/157 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.253); catalogued as COSV101471188, COSV101471220; called by muse, mutect2, varscan2
- PSMD12 | c.1001A>G p.E334G | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV62065373; called by muse, mutect2, varscan2
- PTH | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.025); catalogued as COSV56378328, COSV99961719; called by muse, mutect2, varscan2
- RALGAPA1 | c.4609C>T p.H1537Y | Missense Mutation (SNP) | VAF 30/146 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.304); catalogued as COSV51880042; called by muse, mutect2, varscan2
- RBL1 | c.3023G>T p.G1008V | Missense Mutation (SNP) | VAF 26/196 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.544); catalogued as rs779031311, COSV60334055; called by muse, mutect2, varscan2
- RBL1 | c.3022G>T p.G1008C | Missense Mutation (SNP) | VAF 26/200 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as COSV100726913; called by muse, mutect2, varscan2
- REG1B | c.115G>T p.G39C | Missense Mutation (SNP) | VAF 59/312 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV59305024; called by mutect2, varscan2
- REG3A | c.150C>G p.H50Q | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.255); catalogued as COSV59409112; called by muse, mutect2
- RFT1 | c.64-2A>T p.X22_splice | Splice Site (SNP) | VAF 4/30 reads (13%) | catalogued as rs554732067, COSV56248548; called by muse, mutect2, varscan2
- RGS13 | c.8G>T p.R3M | Missense Mutation (SNP) | VAF 29/189 reads (15%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.635); catalogued as COSV67345847; called by muse, mutect2, varscan2
- RGS4 | c.4T>A p.C2S | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV63357120; called by muse, mutect2, varscan2
- RGS6 | c.342+1del | Frame Shift Del (DEL) | VAF 10/91 reads (11%) | catalogued as COSV59595046; called by mutect2, varscan2
- RLIM | c.932G>T p.G311V | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.454); catalogued as COSV60325937; called by muse, mutect2
- RNF128 | c.1224C>G p.N408K (on ENST00000255499 / NM_194463.2; = p.N382K on NM_024539.3) | Missense Mutation (SNP) | VAF 22/350 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55250117; called by muse, mutect2
- RUNX1T1 | c.1264G>C p.D422H (on ENST00000265814 / NM_001198628.1; = p.D395H on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/204 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as COSV56142543; called by muse, mutect2
- RYR2 | c.2126G>C p.G709A | Missense Mutation (SNP) | VAF 18/149 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.737); catalogued as COSV100768632; called by muse, varscan2
- RYR2 | c.6475C>A p.P2159T | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100768633; called by muse, mutect2, varscan2
- RYR2 | c.6476C>G p.P2159R | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100768636, COSV100772841; called by muse, mutect2, varscan2
- SCN10A | c.3337G>T p.D1113Y | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); catalogued as COSV71860911; called by muse, mutect2, varscan2
- SELENOI | c.167C>T p.S56F | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.949); catalogued as COSV99564298; called by muse, mutect2, varscan2
- SELP | c.1876C>A p.P626T | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.662); catalogued as COSV55248705, COSV55250219; called by muse, mutect2, varscan2
- SEMG2 | c.1634G>T p.R545I | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65647340; called by muse, mutect2, varscan2
- SERPINA4 | c.263T>C p.M88T | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as COSV54069443; called by muse, mutect2, varscan2
- SETBP1 | c.1592G>T p.R531M | Missense Mutation (SNP) | VAF 52/243 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56317942; called by muse, mutect2, varscan2
- SETD4 | c.79G>T p.E27* | Nonsense Mutation (SNP) | VAF 21/142 reads (15%) | catalogued as COSV59771768; called by muse, mutect2, varscan2
- SEZ6L | c.1643A>T p.Q548L | Missense Mutation (SNP) | VAF 18/208 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.338); catalogued as COSV50660618; called by muse, mutect2
- SI | c.4889G>T p.W1630L | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0.174); catalogued as COSV52272559, COSV52278216, COSV52292148; called by muse, mutect2
- SLC22A16 | c.722G>T p.W241L | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1021796582, COSV57928788; called by muse, mutect2, varscan2
- SLC27A6 | c.685+1G>A p.X229_splice | Splice Site (SNP) | VAF 11/52 reads (21%) | catalogued as COSV52481875; called by muse, mutect2, varscan2
- SLC32A1 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs775782051, COSV54146222; called by muse, mutect2, varscan2
- SLC6A17 | c.1546G>T p.G516* | Nonsense Mutation (SNP) | VAF 11/98 reads (11%) | catalogued as COSV58992223, COSV58995777; called by muse, mutect2
- SLC9A2 | c.1563G>C p.W521C | Missense Mutation (SNP) | VAF 16/282 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV52130662; called by muse, mutect2
- SLIT1 | c.1528G>T p.D510Y | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); catalogued as COSV56586614; called by muse, mutect2, varscan2
- SLITRK1 | c.616G>A p.E206K | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); catalogued as COSV65675001; called by muse, mutect2, varscan2
- SLITRK2 | c.196C>T p.Q66* | Nonsense Mutation (SNP) | VAF 28/203 reads (14%) | catalogued as COSV59424320; called by muse, mutect2, varscan2
- SLITRK5 | c.203G>T p.R68L | Missense Mutation (SNP) | VAF 68/342 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.509); catalogued as COSV61521971, COSV61527533; called by muse, mutect2, varscan2
- SPEF2 | c.1003A>T p.I335F | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV56795802; called by muse, mutect2, varscan2
- SPTA1 | c.4956G>T p.L1652F | Missense Mutation (SNP) | VAF 23/192 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as COSV63751270; called by muse, mutect2, varscan2
- SPZ1 | c.1237C>A p.H413N | Missense Mutation (SNP) | VAF 23/166 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.324); catalogued as COSV57062825, COSV57063279; called by muse, mutect2, varscan2
- STARD8 | c.2044G>T p.A682S | Missense Mutation (SNP) | VAF 21/138 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.85); catalogued as COSV52924282; called by muse, mutect2, varscan2
- STK10 | c.2700G>T p.K900N | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51572737; called by muse, mutect2, varscan2
- SULT1C4 | c.173C>A p.T58K | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1032159049, COSV55597102; called by muse, mutect2, varscan2
- SVEP1 | c.10070G>T p.C3357F | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52837842; called by muse, mutect2, varscan2
- SYCP3 | c.22T>A p.Y8N | Missense Mutation (SNP) | VAF 68/293 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV57148664; called by muse, mutect2, varscan2
- SYNE2 | c.13453G>T p.V4485L | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.196); catalogued as COSV59945957, COSV59967049; called by muse, mutect2, varscan2
- SYTL4 | c.943C>A p.H315N | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV52166651; called by muse, mutect2, varscan2
- TAF1L | c.4279C>A p.P1427T | Missense Mutation (SNP) | VAF 94/404 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV54260183, COSV54260241, COSV99645193; called by muse, varscan2
- TBC1D10A | c.559A>T p.T187S | Missense Mutation (SNP) | VAF 18/131 reads (14%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.557); catalogued as COSV53163466; called by muse, mutect2, varscan2
- TCF7L1 | c.1196C>T p.A399V | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV56397509; called by muse, mutect2, varscan2
- TDRD5 | c.318G>T p.K106N | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV54241002; called by muse, mutect2, varscan2
- TFDP1 | c.338G>A p.G113D | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV64739827; called by muse, mutect2, varscan2
- TG | c.2932C>T p.P978S | Missense Mutation (SNP) | VAF 11/217 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55071398; called by muse, mutect2
- TNFAIP8L3 | c.746T>A p.I249N | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59528440; called by muse, mutect2, varscan2
- TNFRSF21 | c.979C>G p.P327A | Missense Mutation (SNP) | VAF 34/299 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV57281144, COSV57284201; called by muse, mutect2, varscan2
- TNN | c.2872G>A p.G958R | Missense Mutation (SNP) | VAF 17/138 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1157961557, COSV53424163; called by muse, mutect2, varscan2
- TNR | c.1316C>A p.S439* | Nonsense Mutation (SNP) | VAF 53/377 reads (14%) | catalogued as COSV54872472, COSV54878581; called by muse, mutect2, varscan2
- TRPC4 | c.1888C>G p.H630D | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as COSV58996232; called by muse, mutect2
- TRPM2 | c.2683G>T p.G895W | Missense Mutation (SNP) | VAF 48/266 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55968098; called by muse, mutect2, varscan2
- TYR | c.176T>A p.L59H | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.566); catalogued as COSV54473061; called by muse, mutect2, varscan2
- UAP1 | c.241A>T p.T81S | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.77); PolyPhen benign (0.01); catalogued as rs375954138; called by muse, mutect2, varscan2
- UBQLN3 | c.1325C>G p.P442R | Missense Mutation (SNP) | VAF 20/164 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.83); catalogued as COSV100293421, COSV61163673; called by muse, mutect2, varscan2
- UGT1A10 | c.272T>A p.M91K | Missense Mutation (SNP) | VAF 32/208 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100761429; called by muse, mutect2, varscan2
- ULK1 | c.1465G>T p.V489F | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.38); PolyPhen benign (0.127); catalogued as COSV58855757; called by muse, mutect2, varscan2
- UNC13A | c.1655C>A p.T552K | Missense Mutation (SNP) | VAF 51/180 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); catalogued as COSV53192354; called by muse, mutect2, varscan2
- UNC13C | c.6175G>A p.G2059R | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.996); catalogued as COSV52859208; called by muse, mutect2, varscan2
- USH2A | c.9281C>A p.A3094D | Missense Mutation (SNP) | VAF 23/225 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV56351602; called by muse, mutect2, varscan2
- USP24 | c.5207A>T p.Q1736L | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53765410; called by muse, mutect2, varscan2
- UTP6 | c.924G>T p.R308S | Missense Mutation (SNP) | VAF 67/333 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.427); catalogued as COSV55572453; called by muse, mutect2, varscan2
- WSCD1 | c.577G>C p.E193Q | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.972); catalogued as COSV58494027, COSV58494854; called by muse, mutect2, varscan2
- XCL1 | c.282G>T p.M94I | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV63191894; called by muse, mutect2, varscan2
- XIRP2 | c.7901G>T p.G2634V (on ENST00000628543; = p.G2809V on NM_152381.6) | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV54692078, COSV54701172; called by muse, mutect2, varscan2
- YLPM1 | c.3213G>T p.K1071N | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.017); catalogued as COSV53109478; called by muse, mutect2, varscan2
- ZBBX | c.573G>C p.Q191H | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV56786388; called by muse, mutect2, varscan2
- ZBED4 | c.677C>G p.S226C | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV53464971; called by muse, varscan2
- ZBTB24 | c.1034C>G p.T345R | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.93); catalogued as COSV100018339; called by muse, mutect2, varscan2
- ZEB2 | c.1076C>G p.S359C | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); catalogued as COSV57954587; called by muse, mutect2, varscan2
- ZFHX4 | c.1993G>T p.E665* | Nonsense Mutation (SNP) | VAF 11/80 reads (14%) | catalogued as COSV50661307, COSV99261338; called by muse, mutect2, varscan2
- ZFHX4 | c.3185T>A p.L1062Q | Missense Mutation (SNP) | VAF 30/203 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50661459, COSV50819167; called by muse, mutect2, varscan2
- ZFHX4 | c.6478C>A p.Q2160K | Missense Mutation (SNP) | VAF 10/135 reads (7%) | SIFT tolerated (0.85); PolyPhen probably damaging (0.969); catalogued as COSV50661596; called by muse, mutect2
- ZFYVE26 | c.3988A>T p.S1330C | Missense Mutation (SNP) | VAF 22/252 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.754); catalogued as COSV61326691; called by muse, mutect2
- ZGRF1 | c.4077G>T p.M1359I | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.306); catalogued as COSV100480824; called by muse, mutect2
- ZKSCAN7 | c.1100C>G p.S367C | Missense Mutation (SNP) | VAF 20/192 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.737); catalogued as COSV99837481; called by muse, mutect2, varscan2
- ZNF445 | c.1547G>C p.R516T | Missense Mutation (SNP) | VAF 10/164 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.247); catalogued as rs1303059424, COSV68538686; called by muse, mutect2
- ZNF638 | c.1916G>T p.C639F | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV52484774; called by muse, mutect2, varscan2
- ZNF780A | c.1513G>T p.E505* | Nonsense Mutation (SNP) | VAF 29/125 reads (23%) | catalogued as rs867693861, COSV61815516; called by muse, mutect2, varscan2
- FYB2 | c.1205del p.P402Hfs*9 | Frame Shift Del (DEL) | VAF 15/71 reads (21%) | called by mutect2, pindel, varscan2
- GAS2L2 | c.1729G>T p.D577Y | Missense Mutation (SNP) | VAF 32/145 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- HSPG2 | c.3778G>T p.G1260C | Missense Mutation (SNP) | VAF 39/263 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HSPG2 | c.3777G>T p.Q1259H | Missense Mutation (SNP) | VAF 39/265 reads (15%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.671); called by muse, mutect2, varscan2
- KBTBD3 | c.1249del p.D417Tfs*6 | Frame Shift Del (DEL) | VAF 7/43 reads (16%) | called by mutect2, pindel, varscan2
- LMNTD1 | c.46G>T p.V16L | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.015); called by muse, mutect2
- MUC2 | c.1352C>A p.A451D | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- MYH6 | c.1120del p.A374Rfs*18 | Frame Shift Del (DEL) | VAF 16/143 reads (11%) | called by mutect2, pindel, varscan2
- NOP56 | c.950del p.N317Tfs*23 | Frame Shift Del (DEL) | VAF 9/72 reads (13%) | called by mutect2, pindel, varscan2
- OR11H1 | c.568G>T p.A190S | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.363); called by mutect2, varscan2
- PCDHGA9 | c.601del p.D201Tfs*30 | Frame Shift Del (DEL) | VAF 6/49 reads (12%) | called by mutect2, pindel*, varscan2
- SPATA31A1 | c.2971C>A p.H991N | Missense Mutation (SNP) | VAF 38/327 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- STARD8 | c.991C>A p.P331T | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.276); called by muse, mutect2
- SUPT20HL1 | c.875C>A p.T292K | Missense Mutation (SNP) | VAF 73/306 reads (24%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- ABCB1 | c.1446C>A p.T482= | Silent (SNP) | VAF 49/319 reads (15%) | catalogued as COSV55948467; called by muse, mutect2, varscan2
- AC093827.5 | c.309G>C p.L103= | Silent (SNP) | VAF 14/83 reads (17%) | catalogued as rs756413401, COSV55745067; called by muse, mutect2, varscan2
- ACE | c.2748G>T p.T916= | Silent (SNP) | VAF 18/80 reads (23%) | catalogued as COSV52005307; called by muse, mutect2, varscan2
- ADH6 | c.726C>G p.L242= | Silent (SNP) | VAF 99/631 reads (16%) | catalogued as COSV52955774; called by muse, mutect2, varscan2
- AFF2 | c.1674G>C p.L558= | Silent (SNP) | VAF 117/713 reads (16%) | catalogued as COSV53984000; called by muse, mutect2, varscan2
- AHNAK | c.17454G>C p.G5818= | Silent (SNP) | VAF 33/234 reads (14%) | catalogued as COSV57209547; called by muse, mutect2, varscan2
- AMER2 | c.1639C>A p.R547= | Silent (SNP) | VAF 13/120 reads (11%) | catalogued as COSV100766255, COSV63436953; called by muse, mutect2, varscan2
- ASTN1 | c.640C>A p.R214= | Silent (SNP) | VAF 7/69 reads (10%) | catalogued as rs534788724, COSV56065806, COSV56077889; called by muse, mutect2, varscan2
- BAG6 | c.1329G>A p.Q443= | Silent (SNP) | VAF 24/447 reads (5%) | catalogued as COSV52987887; called by muse, mutect2
- BMP10 | c.552G>T p.L184= | Silent (SNP) | VAF 16/124 reads (13%) | catalogued as COSV54894751; called by muse, mutect2, varscan2
- BRINP3 | c.1536C>A p.A512= | Silent (SNP) | VAF 40/244 reads (16%) | catalogued as COSV66519069; called by muse, mutect2, varscan2
- BRSK1 | c.1683G>A p.L561= | Silent (SNP) | VAF 24/74 reads (32%) | catalogued as COSV100473643, COSV58665677; called by muse, mutect2, varscan2
- CACNA1F | c.5292G>C p.G1764= | Silent (SNP) | VAF 16/105 reads (15%) | catalogued as COSV59903843; called by muse, mutect2, varscan2
- CACNA1I | c.2586G>T p.V862= | Silent (SNP) | VAF 13/121 reads (11%) | catalogued as COSV60804839; called by muse, mutect2, varscan2
- CDH23 | c.9891C>T p.L3297= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV56456108; called by muse, mutect2
- CDRT1 | c.1590G>A p.T530= | Silent (SNP) | VAF 5/76 reads (7%) | catalogued as rs1418220684, COSV100599778, COSV100599877; called by muse, mutect2
- CFAP65 | c.681G>A p.A227= | Silent (SNP) | VAF 37/224 reads (17%) | catalogued as rs551813462, COSV55389908; called by muse, mutect2, varscan2
- CLN3 | c.1236G>A p.Q412= (on ENST00000360019 / NM_001286104.2; = p.Q436= on NM_000086.2) | Silent (SNP) | VAF 17/105 reads (16%) | catalogued as COSV61105478; called by muse, mutect2, varscan2
- CLSTN1 | c.1467G>T p.P489= (on ENST00000377298 / NM_001009566.3; = p.P479= on NM_014944.4) | Silent (SNP) | VAF 31/173 reads (18%) | catalogued as rs778981522, COSV63647405; called by muse, mutect2, varscan2
- CLVS1 | c.186C>G p.T62= | Silent (SNP) | VAF 13/62 reads (21%) | catalogued as COSV57973048; called by muse, mutect2, varscan2
- CNTN1 | c.1599C>A p.A533= | Silent (SNP) | VAF 22/75 reads (29%) | catalogued as COSV61638314; called by muse, mutect2, varscan2
- DAB1 | c.57C>A p.S19= | Silent (SNP) | VAF 24/145 reads (17%) | catalogued as rs187718590, COSV59725571; called by muse, mutect2, varscan2
- DLGAP4 | c.819C>A p.P273= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as COSV59416399; called by muse, mutect2, varscan2
- DOCK10 | c.3093C>A p.V1031= | Silent (SNP) | VAF 19/115 reads (17%) | catalogued as COSV51367581; called by muse, mutect2, varscan2
- FAM13B | c.613C>T p.L205= | Silent (SNP) | VAF 18/155 reads (12%) | catalogued as rs1013623265, COSV50365372; called by muse, mutect2, varscan2
- FAT2 | c.6828C>A p.V2276= | Silent (SNP) | VAF 30/176 reads (17%) | catalogued as COSV55816887; called by muse, mutect2, varscan2
- FAT4 | c.10260A>T p.P3420= | Silent (SNP) | VAF 38/274 reads (14%) | catalogued as COSV58678658; called by muse, mutect2, varscan2
- FEZ1 | c.192T>C p.N64= | Silent (SNP) | VAF 23/145 reads (16%) | catalogued as COSV54027632; called by muse, mutect2, varscan2
- FLG2 | c.6735C>G p.S2245= | Silent (SNP) | VAF 81/618 reads (13%) | catalogued as COSV66167663; called by muse, mutect2, varscan2
- FYB2 | c.1452T>C p.S484= | Silent (SNP) | VAF 19/164 reads (12%) | catalogued as COSV58583910; called by muse, mutect2, varscan2
- GCM1 | c.648T>A p.G216= | Silent (SNP) | VAF 31/193 reads (16%) | catalogued as COSV52521419; called by muse, mutect2, varscan2
- GOLGA8A | c.1707G>T p.A569= (on ENST00000432566; = p.A541= on NM_181077.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV100781585; called by mutect2, varscan2
- GP2 | c.828C>A p.T276= (on ENST00000381362 / NM_001007240.3; = p.T273= on NM_001502.4) | Silent (SNP) | VAF 16/185 reads (9%) | catalogued as COSV56892897; called by muse, mutect2
- GRIN1 | c.2499C>A p.I833= | Silent (SNP) | VAF 27/121 reads (22%) | catalogued as COSV59294137; called by muse, mutect2, varscan2
- HGF | c.1767C>A p.V589= | Silent (SNP) | VAF 9/90 reads (10%) | catalogued as COSV55947418; called by muse, mutect2
- HK3 | c.2340G>A p.Q780= | Silent (SNP) | VAF 37/227 reads (16%) | catalogued as COSV52838526; called by muse, mutect2, varscan2
- HOXA3 | c.471C>A p.P157= | Silent (SNP) | VAF 31/249 reads (12%) | catalogued as COSV57825859; called by muse, mutect2, varscan2
- IGFBP3 | c.438C>A p.A146= | Silent (SNP) | VAF 20/141 reads (14%) | catalogued as COSV51872211; called by muse, mutect2, varscan2
- IL23R | c.831G>T p.V277= | Silent (SNP) | VAF 26/100 reads (26%) | catalogued as COSV61373790; called by muse, mutect2, varscan2
- ITGAX | c.2493C>T p.Y831= | Silent (SNP) | VAF 24/135 reads (18%) | catalogued as rs146985733; called by muse, mutect2, varscan2
- LONP1 | c.1209C>T p.I403= | Silent (SNP) | VAF 52/242 reads (21%) | catalogued as rs764862589, COSV62261192; called by muse, mutect2, varscan2
- LY6D | c.117G>A p.P39= | Silent (SNP) | VAF 37/155 reads (24%) | catalogued as rs138562115; called by muse, mutect2, varscan2
- MICAL3 | c.4809C>T p.S1603= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as rs558369380, COSV71588223; called by muse, mutect2, varscan2
- MRC2 | c.3036C>T p.V1012= | Silent (SNP) | VAF 21/125 reads (17%) | catalogued as rs1568071776, COSV57638320; called by muse, mutect2, varscan2
- MUC17 | c.5697C>A p.T1899= | Silent (SNP) | VAF 66/555 reads (12%) | catalogued as COSV100072048; called by muse, mutect2, varscan2
- NCCRP1 | c.567G>C p.L189= | Silent (SNP) | VAF 55/226 reads (24%) | catalogued as COSV59212379; called by muse, mutect2, varscan2
- NDST4 | c.714A>G p.L238= | Silent (SNP) | VAF 27/180 reads (15%) | catalogued as COSV52114567; called by muse, mutect2, varscan2
- NLGN4X | c.927G>A p.L309= | Silent (SNP) | VAF 28/161 reads (17%) | catalogued as COSV52011891; called by muse, mutect2, varscan2
- NLRP10 | c.1344T>C p.S448= | Silent (SNP) | VAF 31/218 reads (14%) | catalogued as COSV60779670; called by muse, mutect2, varscan2
- NUTM2A | c.2385G>A p.Q795= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as COSV101095667; called by mutect2, varscan2
- OR10H4 | c.339C>A p.S113= | Silent (SNP) | VAF 91/475 reads (19%) | catalogued as COSV59061529; called by muse, mutect2, varscan2
- OR10K2 | c.60G>T p.L20= | Silent (SNP) | VAF 10/70 reads (14%) | catalogued as COSV59220861; called by muse, varscan2
- OR2T2 | c.286C>T p.L96= | Silent (SNP) | VAF 26/441 reads (6%) | catalogued as rs1273517884, COSV61617727, COSV61617895; called by muse, mutect2
- OR51E1 | c.820C>T p.L274= | Silent (SNP) | VAF 29/220 reads (13%) | catalogued as rs1387631766, COSV67809625; called by muse, mutect2, varscan2
- OR51M1 | c.634C>T p.L212= | Silent (SNP) | VAF 24/119 reads (20%) | catalogued as COSV60784225; called by muse, mutect2, varscan2
- OR5D18 | c.543G>A p.E181= | Silent (SNP) | VAF 32/273 reads (12%) | catalogued as COSV61736696; called by muse, mutect2, varscan2
- OR5M1 | c.270G>A p.K90= | Silent (SNP) | VAF 13/93 reads (14%) | catalogued as rs532045516, COSV101591561, COSV73202033, COSV73202262; called by muse, mutect2, varscan2
- PCDHB7 | c.735G>A p.S245= | Silent (SNP) | VAF 20/136 reads (15%) | catalogued as rs781976935, COSV50760322; called by muse, mutect2, varscan2
- PDZD2 | c.5532C>T p.G1844= | Silent (SNP) | VAF 30/203 reads (15%) | catalogued as rs776990963, COSV56855312; called by muse, mutect2, varscan2
- PEAR1 | c.684C>T p.F228= | Silent (SNP) | VAF 92/462 reads (20%) | catalogued as rs148520058, COSV52772242; called by muse, varscan2
- PFKL | c.189G>A p.E63= | Silent (SNP) | VAF 12/122 reads (10%) | catalogued as COSV62463134; called by muse, mutect2, varscan2
- PIK3CG | c.1701C>T p.L567= | Silent (SNP) | VAF 25/121 reads (21%) | catalogued as COSV63247277; called by muse, mutect2, varscan2
- PLCD4 | c.1236G>A p.L412= | Silent (SNP) | VAF 6/67 reads (9%) | catalogued as COSV68842379; called by muse, mutect2
- PLXNA4 | c.2979C>A p.P993= | Silent (SNP) | VAF 93/724 reads (13%) | catalogued as COSV58116291; called by muse, mutect2, varscan2
- PRDM9 | c.66C>A p.P22= | Silent (SNP) | VAF 21/78 reads (27%) | catalogued as COSV57004665, COSV57007897; called by muse, mutect2, varscan2
- PRG4 | c.1908C>A p.T636= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as COSV63355215; called by muse, varscan2
- RHEX | c.477T>A p.P159= | Silent (SNP) | VAF 36/147 reads (24%) | catalogued as COSV100520035; called by muse, mutect2, varscan2
- RTL5 | c.519C>T p.F173= | Silent (SNP) | VAF 13/61 reads (21%) | catalogued as COSV65452895; called by muse, mutect2, varscan2
- RYR1 | c.14670G>T p.V4890= | Silent (SNP) | VAF 37/131 reads (28%) | catalogued as COSV62093936; called by muse, mutect2, varscan2
- SCFD2 | c.51G>T p.V17= | Silent (SNP) | VAF 17/102 reads (17%) | catalogued as COSV66370485; called by muse, mutect2, varscan2
- SCN4A | c.465C>G p.P155= | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as COSV71126278; called by muse, mutect2, varscan2
- SEPTIN6 | c.927G>A p.K309= | Silent (SNP) | VAF 13/114 reads (11%) | catalogued as COSV59713293; called by muse, mutect2, varscan2
- SEPTIN6 | c.603C>T p.I201= | Silent (SNP) | VAF 52/360 reads (14%) | catalogued as COSV59713315; called by muse, mutect2, varscan2
- SF3B2 | c.1929A>T p.P643= | Silent (SNP) | VAF 4/52 reads (8%) | catalogued as COSV59427582; called by muse, mutect2
- SH3PXD2B | c.1500A>T p.S500= | Silent (SNP) | VAF 37/228 reads (16%) | catalogued as COSV61125857; called by muse, mutect2, varscan2
- SHROOM3 | c.5274G>A p.E1758= | Silent (SNP) | VAF 9/89 reads (10%) | catalogued as COSV56026501; called by muse, mutect2
- SLC18A2 | c.807G>T p.V269= | Silent (SNP) | VAF 17/88 reads (19%) | catalogued as COSV53689554; called by muse, mutect2, varscan2
- SLC19A3 | c.1443G>T p.V481= | Silent (SNP) | VAF 30/174 reads (17%) | catalogued as COSV51452172; called by muse, mutect2, varscan2
- SLC23A1 | c.1020C>T p.Y340= | Silent (SNP) | VAF 28/173 reads (16%) | catalogued as rs776506562, COSV100811901; called by muse, mutect2, varscan2
- SLC7A14 | c.336C>T p.V112= | Silent (SNP) | VAF 7/52 reads (13%) | catalogued as COSV51580123; called by muse, mutect2, varscan2
- SOX1 | c.361C>A p.R121= | Silent (SNP) | VAF 8/82 reads (10%) | catalogued as COSV100446822, COSV58379340; called by muse, mutect2
- STARD8 | c.360C>A p.A120= | Silent (SNP) | VAF 18/150 reads (12%) | catalogued as COSV52924014; called by muse, mutect2, varscan2
- SYNE2 | c.11844G>T p.V3948= | Silent (SNP) | VAF 22/124 reads (18%) | catalogued as COSV59945945; called by muse, mutect2, varscan2
- TAF1L | c.1941C>G p.L647= | Silent (SNP) | VAF 49/215 reads (23%) | catalogued as rs763041951, COSV54257319, COSV54260191; called by muse, mutect2, varscan2
- TERT | c.2661G>T p.L887= | Silent (SNP) | VAF 25/196 reads (13%) | catalogued as rs756519152, COSV57208279; called by muse, mutect2, varscan2
- TFDP2 | c.1212C>T p.F404= (on ENST00000489671 / NM_001178139.2; = p.F344= on NM_006286.5) | Silent (SNP) | VAF 11/104 reads (11%) | catalogued as COSV57706560, COSV57707694; called by muse, mutect2, varscan2
- TGM4 | c.723A>C p.T241= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as COSV56093422; called by muse, mutect2
- TSHZ2 | c.2760C>T p.D920= | Silent (SNP) | VAF 18/107 reads (17%) | catalogued as COSV61587895; called by muse, mutect2, varscan2
- UCP2 | c.789G>A p.K263= | Silent (SNP) | VAF 32/194 reads (16%) | catalogued as rs1396073290, COSV60104509; called by muse, mutect2, varscan2
- USP6NL | c.564G>T p.G188= | Silent (SNP) | VAF 32/110 reads (29%) | catalogued as COSV53210402; called by muse, mutect2, varscan2
- ZNF618 | c.2415C>T p.A805= (on ENST00000374126 / NM_001318042.2; = p.A712= on NM_133374.2) | Silent (SNP) | VAF 13/71 reads (18%) | catalogued as rs748306518, COSV55919399; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73851049 A>T | 3'Flank (SNP) | VAF 33/212 reads (16%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65503097 C>G | 5'Flank (SNP) | VAF 3/15 reads (20%) | called by muse, mutect2
- FAM27E5 | n.416G>A | RNA (SNP) | VAF 13/80 reads (16%) | catalogued as rs1449655408; called by muse, mutect2, varscan2
- IL36B | c.261+990G>T | Intron (SNP) | VAF 24/122 reads (20%) | catalogued as COSV99382505; called by muse, mutect2, varscan2
- OBSCN | c.18662-2140T>C | Intron (SNP) | VAF 9/47 reads (19%) | catalogued as rs749177712, COSV99474480; called by muse, mutect2, varscan2
- RGS6 | c.*2C>T | 3'UTR (SNP) | VAF 15/98 reads (15%) | catalogued as rs1347206888, COSV59570843; called by muse, mutect2
